Somatic mutation profile of tumor specimen MP2PRT-PARPLH-TMP1-A (aliquot MP2PRT-PARPLH-TMP1-A-1-0-D-A83C-36) from MP2PRT case MP2PRT-PARPLH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,709 days).
Specimen MP2PRT-PARPLH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7981a06d-8991-49c5-afa7-845aedd2afc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPLH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPLH-NB1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76d82d10-6ac3-4249-a7da-99745e7d6725

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT6A | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 307/720 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV58107815; called by muse, mutect2, varscan2
- PCDHA2 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); catalogued as COSV65364392; called by muse, mutect2, varscan2
- PCDHAC1 | c.1450C>A p.L484M | Missense Mutation (SNP) | VAF 230/598 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53849904; called by muse, mutect2
- TMEM11 | c.102G>C p.E34D | Missense Mutation (SNP) | VAF 50/362 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs760509180; called by muse, varscan2
- ZBTB22 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 324/716 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV56467733; called by muse, mutect2, varscan2
- HARS2 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 85/215 reads (40%) | called by muse, mutect2, varscan2
- IGHV5-51 | chr14:106578742 TGT>GGTTGG | Missense Mutation (INS) | VAF 133/148 reads (90%) | called by pindel, varscan2*
- IVL | c.1405C>A p.Q469K | Missense Mutation (SNP) | VAF 250/521 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); called by mutect2, varscan2
- OR4E2 | c.632T>C p.F211S | Missense Mutation (SNP) | VAF 153/318 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC9A6 | c.1492A>T p.T498S | Missense Mutation (SNP) | VAF 203/432 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ZDBF2 | c.5467G>T p.V1823L | Missense Mutation (SNP) | VAF 94/209 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- BEND2 | c.1602C>T p.L534= | Silent (SNP) | VAF 119/414 reads (29%) | catalogued as rs149324488, COSV66215883; called by muse, mutect2, varscan2
- FRMD8 | c.1209G>A p.L403= | Silent (SNP) | VAF 274/576 reads (48%) | called by muse, mutect2, varscan2
- METTL6 | c.9T>C p.S3= | Silent (SNP) | VAF 95/199 reads (48%) | catalogued as rs1391017442; called by muse, mutect2, varscan2
